Somatic mutation profile of tumor specimen TCGA-JY-A6FH-01A (aliquot TCGA-JY-A6FH-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.5 years (19,549 days).
Specimen TCGA-JY-A6FH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed19ab1-cb07-4e74-8717-9c00d82d36c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FH-10A (Blood Derived Normal), aliquot TCGA-JY-A6FH-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33bea3ac-50d3-4071-bd7b-4351a556a1a6

The open-access MAF lists 142 somatic variants for this specimen: 108 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 32, Frame Shift Ins 4, Nonsense Mutation 3, Splice Region 2, RNA 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSA | c.684+1G>A p.X228_splice | Splice Site (SNP) | VAF 21/24 reads (88%) | catalogued as rs146371968, CS951348, COSV99332390; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/29 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as rs374483089; called by muse, mutect2, varscan2
- ARHGAP31 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51798948; called by muse, mutect2, varscan2
- ARHGEF10 | c.1664C>T p.T555M (on ENST00000398564; = p.T530M on NM_014629.4) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781482995; called by muse, mutect2, varscan2
- ATP10A | c.2463A>T p.E821D | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.147); catalogued as COSV100790922; called by muse, mutect2, varscan2
- CDH8 | c.1762A>C p.S588R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54872083; called by muse, mutect2, varscan2
- CER1 | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV66603100; called by muse, mutect2, varscan2
- COL5A1 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1472700264, COSV65669354; called by muse, mutect2, varscan2
- GRAMD1B | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 36/49 reads (73%) | catalogued as rs969160143, COSV59206202; called by muse, mutect2, varscan2
- GRP | c.145T>G p.L49V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56879169; called by muse, mutect2, varscan2
- INHBA | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.096); catalogued as rs765588441; called by muse, mutect2, varscan2
- LPIN2 | c.1069T>G p.S357A | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55236979; called by muse, mutect2, varscan2
- MAST1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52241239; called by muse, mutect2, varscan2
- MGA | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54953414, COSV54954701, COSV54961704; called by muse, mutect2
- MKRN3 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58809877; called by muse, mutect2, varscan2
- MPO | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs936805233; called by muse, mutect2, varscan2
- MUC17 | c.6076C>A p.P2026T | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60306548; called by muse, mutect2, varscan2
- NCKAP5 | c.4096A>T p.S1366C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV58445055; called by muse, mutect2, varscan2
- NELL1 | c.2102A>T p.K701M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as COSV54266494; called by muse, mutect2, varscan2
- NEXN | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs367871780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP93 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.332); catalogued as rs754633729, COSV57429982; called by muse, mutect2, varscan2
- OGDHL | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746449761, COSV65103575; called by muse, mutect2, varscan2
- OR10Z1 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs369776894; called by muse, varscan2
- OR2L8 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100594040; called by muse, mutect2, varscan2
- OR4C16 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs953662794; called by muse, mutect2, varscan2
- OR5W2 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV60614714, COSV60614862; called by muse, mutect2, varscan2
- PHRF1 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as rs1301242625, COSV52751904; called by muse, mutect2, varscan2
- PKHD1 | c.9157T>G p.L3053V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs771015680; called by muse, mutect2, varscan2
- PLD5 | c.967A>G p.S323G (on ENST00000442594; = p.S261G on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV59134006; called by muse, mutect2, varscan2
- PRAMEF7 | c.1063T>G p.L355V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435040; called by mutect2, varscan2
- PTPN7 | c.979C>T p.R327W (on ENST00000495688; = p.R366W on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538790408, COSV58312799; called by muse, mutect2, varscan2
- RHBDD1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as rs147605304; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2
- SHB | c.815A>C p.Y272S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66621266; called by muse, mutect2, varscan2
- SLC30A8 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.3); catalogued as rs1482242249; called by muse, mutect2, varscan2
- SPATA5L1 | c.2182C>A p.P728T | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59744241; called by muse, mutect2, varscan2
- UQCRHL | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.88); PolyPhen benign (0.035); catalogued as rs764654397, COSV72331662; called by muse, mutect2, varscan2
- ZMYM4 | c.2873C>T p.S958F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100110551, COSV58915115; called by muse, mutect2, varscan2
- AACS | c.1527G>C p.K509N | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT tolerated (0.28); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ABCA10 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ABCA13 | c.1006T>G p.S336A | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- APC | c.875dup p.L292Ffs*4 | Frame Shift Ins (INS) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- ARAP2 | c.1806A>C p.K602N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ATP11C | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CADPS | c.3824A>G p.D1275G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- CADPS | c.1577G>C p.G526A | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC191 | c.1578A>C p.E526D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CD1D | c.572T>G p.L191R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CITED2 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.116); called by muse, mutect2
- COL12A1 | c.8619G>T p.K2873N | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.11226G>T p.E3742D (on ENST00000409039; = p.E3681D on NM_207437.3) | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK1 | c.3500G>A p.G1167E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DRD3 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DROSHA | c.1501G>C p.V501L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- EPGN | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EXT2 | c.1307A>C p.K436T (on ENST00000343631; = p.K469T on NM_000401.3) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.859T>C p.S287P | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- EZH1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- FBXO10 | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GALNT17 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GARNL3 | c.2822G>C p.S941T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXB9 | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- HRG | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGHV3-53 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- IGHV3-66 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- INO80D | c.2467T>C p.S823P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LMAN1L | c.1006_1012dup p.K338Tfs*15 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, varscan2
- LMAN1L | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.142); called by muse, varscan2
- LNX2 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- LONRF1 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LRRC4C | c.1919T>A p.I640N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC6 | c.6240_6252del p.A2081Lfs*30 | Frame Shift Del (DEL) | VAF 41/76 reads (54%) | called by pindel, varscan2
- NDUFA9 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NIN | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NPC1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, varscan2
- NR5A2 | c.605C>T p.A202V (on ENST00000367362 / NM_205860.3; = p.A156V on NM_003822.5) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP133 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5L1 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- OR5T3 | c.924A>C p.E308D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHC2 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PIDD1 | c.1482G>A p.Q494= | Splice Region (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.1297T>G p.F433V | Missense Mutation (SNP) | VAF 198/366 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF8 | c.1063T>G p.L355V | Missense Mutation (SNP) | VAF 132/365 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS38 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMB3 | c.592A>T p.R198W | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM10 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- RNH1 | c.1190dup p.N397Kfs*6 | Frame Shift Ins (INS) | VAF 36/109 reads (33%) | called by mutect2, pindel, varscan2
- RPL7L1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SETDB2 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.301); called by muse, mutect2
- SLC10A7 | c.952T>G p.L318V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC45A4 | c.1883C>G p.S628C (on ENST00000517878 / NM_001286646.2; = p.S577C on NM_001080431.2) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLC6A18 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLCO1B3 | c.682T>C p.S228P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SMARCC1 | c.2441A>G p.K814R | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPATA31A3 | c.802T>A p.S268T | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.047); called by mutect2, varscan2
- SPEF2 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBC1D8 | c.1378_1385dup p.S464Afs*14 | Frame Shift Ins (INS) | VAF 25/66 reads (38%) | called by mutect2, varscan2
- TBR1 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.23741T>G p.L7914R (on ENST00000591111; = p.L6987R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TUBA3C | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- UGGT1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- UNC13C | c.4104G>A p.E1368= | Splice Region (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2
- YWHAZ | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZC3H12C | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF287 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ABCB5 | c.2646G>A p.E882= (on ENST00000404938 / NM_001163941.2; = p.E437= on NM_178559.6) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV51702924; called by muse, mutect2, varscan2
- ABL1 | c.2430G>A p.P810= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs529175662; called by muse, mutect2, varscan2
- ADCY8 | c.1515C>T p.D505= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs559758167; called by muse, mutect2, varscan2
- AHNAK | c.12468C>T p.G4156= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as rs541326356, COSV57237457; called by muse, mutect2, varscan2
- AKAP6 | c.6312G>A p.L2104= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- BOC | c.1560C>T p.D520= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs757115927; called by muse, mutect2, varscan2
- CCDC144A | c.252C>A p.L84= | Silent (SNP) | VAF 40/51 reads (78%) | catalogued as rs369164566; called by muse, mutect2, varscan2
- CD5L | c.657T>G p.P219= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- CEACAM18 | c.789C>G p.L263= | Silent (SNP) | VAF 47/51 reads (92%) | called by muse, mutect2, varscan2
- CHRNB2 | c.201C>A p.L67= | Silent (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- CNTN3 | c.1428T>G p.T476= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV55165301, COSV55184374; called by muse, mutect2, varscan2
- CSNK1A1L | c.1002G>A p.V334= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV65789787; called by muse, mutect2
- CUBN | c.8655C>T p.N2885= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs369599232; called by muse, mutect2, varscan2
- FFAR2 | c.540G>A p.R180= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99876027; called by muse, mutect2
- GOLGB1 | c.9090C>T p.L3030= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV61461964; called by muse, mutect2, varscan2
- IVL | c.558A>G p.P186= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs372740691; called by muse, mutect2, varscan2
- MUC17 | c.6075T>A p.S2025= | Silent (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- OR10A2 | c.774G>A p.K258= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV56300148; called by muse, mutect2, varscan2
- OR8J1 | c.501T>G p.S167= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1986C>G p.P662= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100866708, COSV100867070, COSV62774779; called by muse, mutect2, varscan2
- PLD5 | c.1578C>T p.D526= (on ENST00000442594; = p.D464= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs369388309; called by muse, mutect2, varscan2
- PLEKHG5 | c.1629C>A p.R543= (on ENST00000400915 / NM_001042663.3; = p.R506= on NM_020631.6) | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV61067988; called by muse, mutect2, varscan2
- R3HDM1 | c.1272C>T p.I424= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- RABGAP1L | c.276A>G p.P92= | Silent (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- RBP3 | c.2613C>T p.P871= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- RIPOR3 | c.2557C>A p.R853= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs371046060; called by muse, varscan2
- RTL4 | c.126A>G p.Q42= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV61205698; called by muse, mutect2, varscan2
- RYR3 | c.519C>T p.L173= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs773675905; called by muse, mutect2, varscan2
- SLC9A3 | c.294C>T p.I98= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs1227710570; called by muse, mutect2, varscan2
- TSLP | c.447T>G p.R149= | Silent (SNP) | VAF 41/51 reads (80%) | called by muse, mutect2, varscan2
- TTN | c.91887T>C p.G30629= (on ENST00000591111; = p.G23205= on NM_003319.4) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV60116478; called by muse, mutect2, varscan2
- ZNF257 | c.340A>C p.R114= | Silent (SNP) | VAF 56/68 reads (82%) | catalogued as COSV71306196, COSV71306850; called by muse, mutect2, varscan2
- SNORD116-17 | n.8T>C | RNA (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- ZNF271P | n.1678C>T | RNA (SNP) | VAF 22/35 reads (63%) | catalogued as rs1569093226; called by muse, mutect2, varscan2
